Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A7IL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A7IL-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Form Revised

Clinical Case Report (For Collection of Cancerous Tissue)

ICD O3
Carcinoma, Hepatocellular
NOS 817013
Site Liver C22.0
10/10/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☒ Male ☐ Female			116	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; fever; tired of eating
Symptoms: Weakness; weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	35 (yrs)	6 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT x	A tumour was found in the liver	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T3 N0 M0 Stage: IIIA		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the right liver.			
Primary Tumor			
Organ	Detailed Location	Size	
Liver tumor	Right liver	6 x 5 x 5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: IIIA			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
LIVER TUMOR	6 x 5 x 5 cm	RIGHT LIVER	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃	N ₀	M ₀	Stage: IIIA

Notes:

[page 5 of 5]
IRB APPROVED

Form Revised

Tel:

Fax:

Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse						Streaming					
Mosaic						Storiform					
Necrosis						Fibrosis					
Lymphocytic Infiltration						Palisading					
Vascular Invasion						Cystic Degeneration					
Clusterized						Bleeding					
Alveolar Formation						Myxoid Change					
Indian File						Psammoma/Calcification					

Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☒ Well ☐ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				

Nuclear Grade: ☒ I ☐ II ☐ III

D1 80% D2 80% D3 80% D4 80%

Final Pathology Report

Histological Diagnosis: Hepatocellular Carcinoma Grade: 1
trabecular type

Comments:

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

Case x (initials):		
Reviewed: initials		

Date: 8/30/13

Reviewed: 8/30/13

Source: NCI Genomic Data Commons file e714ac41-8299-461b-a63d-e3f1ab771016 (TCGA-CC-A7IL.2C629C1E-6849-47F6-B9B4-A97BC0453EFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).